Gene-level copy-number profile of tumor specimen MP2PRT-PAVUPL-TMP1-A from MP2PRT case MP2PRT-PAVUPL, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.7 years (1,724 days).
Specimen MP2PRT-PAVUPL-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 1f08cdd7-df25-4b45-899d-ebbfdd977087.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PAVUPL-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,231 have no estimate.
https://portal.gdc.cancer.gov/files/7963b8ca-3ae1-4cba-aeec-33fa6a8b9cd7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 323; copy number 1: 1,953; copy number 2: 54,769; copy number 3: 1,347.

Homozygous deletions (total copy number 0; autosomes only): 323 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,811,186–89,297,785, 48 genes (within-gene range 0–2): MALLP2, AC244205.1, MIR4436A, IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17, IGKV2-18, IGKV2-19, IGKV3-20, IGKV6-21, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, IGKV2-26, AC244255.1, IGKV1-27, IGKV2-28, IGKV2-29, IGKV2-30, IGKV3-31, IGKV1-32, IGKV1-33, IGKV3-34, IGKV1-35, IGKV2-36, IGKV1-37.
- chr2:89,947,512–90,022,185, 9 genes: IGKV2D-29, IGKV2D-28, IGKV1D-27, IGKV2D-26, IGKV3D-25, IGKV2D-24, IGKV2D-23, IGKV1D-22, IGKV6D-21.
- chr6:26,124,145–26,253,710, 24 genes: H2AC6, H1-4, H2BC5, AL353759.1, LARP1P1, H2BC6, H4C4, H1-12P, AL031777.2, H3C4, H2AC7, H2BC7, AL031777.1, H4C5, H2BC8, H2AC8, H3C5P, H3C6, H2AC9P, H1-3, H4C6, H4C7, H3C7, H2BC9.
- chr7:38,239,580–38,340,998, 17 genes (within-gene range 0–2): TRGC2, TRGJ2, TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6.
- chr7:38,345,030–38,350,022, 2 genes (within-gene range 0–2): TRGV5P, TRGV5.
- chr14:22,168,429–22,552,156, 83 genes (within-gene range 0–2) (broad region; genes not listed).
- chr14:105,672,308–105,771,405, 5 genes (within-gene range 0–2): ELK2AP, IGHA1, IGHEP1, IGHG1, IGHG3.
- chr14:105,851,705–106,538,344, 128 genes (within-gene range 0–1) (broad region; genes not listed).
- chr14:106,564,375–106,579,236, 3 genes (within-gene range 0–1): IGHVII-49-1, IGHV3-50, IGHV5-51.
- chr14:106,584,718–106,584,976, 1 gene (within-gene range 0–1): IGHVII-51-2.
- chr22:22,032,745–22,040,065, 3 genes (within-gene range 0–2): IGLVI-68, AC245452.4, AC245452.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 1,953. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
